Gene-level copy-number profile of tumor specimen C3N-03182-02 from CPTAC case C3N-03182, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 47.8 years (17,461 days).
Specimen C3N-03182-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cb30bb9a-2366-4bb4-b0bc-6482f053dc82.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03182-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/94e1bfb5-eaa2-4867-9108-0a3541c20924

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 555; copy number 1: 5,607; copy number 2: 46,683; copy number 3: 1,845; copy number 4: 4,151; copy number 5: 31; copy number 6: 8; copy number 7: 2; copy number 8: 19.

Homozygous deletions (total copy number 0; autosomes only): 42 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–143,729,570, 7 genes: AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18.
- chr4:4,117,925–4,150,421, 3 genes: AC116562.1, OR7E103P, UNC93B4.
- chr5:58,198–438,291, 16 genes (within-gene range 0–2): AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2.
- chr9:4,386,410–4,386,556, 1 gene: RNU6-694P.
- chr11:4,233,288–4,288,083, 4 genes: SSU72P5, SSU72P2, SSU72P6, SSU72P4.
- chr11:55,602,360–55,666,195, 4 genes: OR4C11, OR4P4, OR4S2, OR4C6.
- chr19:20,416,514–20,571,095, 3 genes (within-gene range 0–2): BNIP3P22, AC008554.1, BNIP3P23.
- chr19:43,192,702–43,269,530, 3 genes: PSG4, CEACAMP10, PSG9.
- chr21:19,345,148–19,345,312, 1 gene: RNU1-139P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 59 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,702,379–1,745,992, 4 genes, copy number 6 (within-gene range 3–6): CDK11A, AL031282.2, AL031282.1, SLC35E2A.
- chr7:37,032–37,477, 1 gene, copy number 7: AC215522.1.
- chr8:7,836,436–7,868,867, 2 genes, copy number 5: DEFB104A, SPAG11A.
- chr16:32,250,620–32,380,049, 7 genes, copy number 5–8: AC133485.3, TP53TG3D, AC133485.2, AC140878.1, AC133548.2, AC133548.1, ACTR3BP3.
- chr16:32,439,069–32,460,362, 3 genes, copy number 6–7: PABPC1P13, AC138915.3, AC138915.1.
- chr16:32,635,673–32,824,645, 16 genes, copy number 5–8: AC133569.1, AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3, AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10, AC137761.1, AC137761.2.
- chr16:33,094,204–33,496,093, 16 genes, copy number 8 (within-gene range 4–8): HERC2P8, AC145350.4, AC145350.1, ABHD17AP9, AC138869.1, AC138869.2, TP53TG3C, AC138869.3, AC141257.2, TP53TG3E, AC141257.3, TP53TG3B, AC141257.1, AC141257.4, TP53TG3F, AC136944.5.
- chr19:42,752,686–42,855,691, 1 gene, copy number 5 (within-gene range 2–5): PSG8.
- chr19:42,821,863–43,171,515, 9 genes, copy number 5 (within-gene range 2–5): PSG8-AS1, PSG10P, PSG1, PSG6, PSG7, CEACAMP7, AC004784.1, PSG11, CEACAMP8.

Autosomal genes at a single copy (total copy number 1): 5,607. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
